Somatic mutation profile of tumor specimen TCGA-AH-6544-01A (aliquot TCGA-AH-6544-01A-11D-1826-10) from TCGA case TCGA-AH-6544, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 60.2 years (21,977 days).
Specimen TCGA-AH-6544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61deaf5b-72a6-4755-8b8d-d731b26b3b1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AH-6544-10A (Blood Derived Normal), aliquot TCGA-AH-6544-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38fbea98-5cb5-43a9-8a6d-9e37b4acb009

The open-access MAF lists 152 somatic variants for this specimen: 114 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 36, Nonsense Mutation 5, Splice Site 3, Splice Region 2, 3'UTR 1, In Frame Ins 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 31/134 reads (23%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 42/143 reads (29%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/127 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 32/234 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.946C>T p.R316W (on ENST00000219054; = p.R237W on NM_001308169.2) | Missense Mutation (SNP) | VAF 81/503 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367739019; called by muse, mutect2, varscan2
- ADAMTS3 | c.1667C>A p.S556* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV99710536; called by muse, mutect2, varscan2
- AMER1 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 54/70 reads (77%) | catalogued as COSV100367055, COSV57658549; called by muse, mutect2, varscan2
- AMER3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs766270630, COSV58465000; called by muse, mutect2, varscan2
- AMY2B | c.468T>G p.C156W | Missense Mutation (SNP) | VAF 112/466 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63713881; called by muse, mutect2, varscan2
- AMY2B | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs150608402; called by muse, mutect2, varscan2
- ANKRD26 | c.4429C>A p.Q1477K | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV65773628; called by muse, mutect2, varscan2
- ANKRD26 | c.3130T>G p.L1044V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65773642; called by muse, mutect2, varscan2
- ANKRD44 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs757773247, COSV56548849; called by muse, mutect2, varscan2
- ANTXR2 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56312465; called by muse, mutect2, varscan2
- AQR | c.4382T>C p.V1461A | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV50029414; called by muse, mutect2, varscan2
- ATG2B | c.2974A>C p.S992R | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63421556; called by muse, mutect2, varscan2
- BOD1L1 | c.3649A>C p.N1217H | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV50006332; called by muse, mutect2, varscan2
- C2CD2 | c.1238G>A p.C413Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61598668; called by muse, mutect2, varscan2
- CAPN6 | c.1841G>C p.R614P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100137032, COSV60697635; called by muse, mutect2, varscan2
- CC2D1A | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58780963; called by muse, mutect2, varscan2
- CD1E | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs371931193, COSV63769863; called by muse, mutect2, varscan2
- CD207 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); catalogued as rs370455494, COSV101338598; called by muse, mutect2, varscan2
- CDH1 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782113, COSV55727148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGNL1 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV55563012; called by muse, mutect2, varscan2
- CIP2A | c.2101G>C p.E701Q | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99843114; called by muse, mutect2
- CNBD1 | c.1250T>G p.I417S | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV73072262; called by muse, mutect2, varscan2
- CNPPD1 | c.1177T>G p.S393A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.351); catalogued as COSV55405533; called by muse, mutect2, varscan2
- COL6A3 | c.7978C>A p.H2660N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99800771; called by muse, mutect2, varscan2
- CP | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs765399242; called by muse, mutect2, varscan2
- CTNNA2 | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV63544405; called by muse, mutect2, varscan2
- E2F5 | c.500A>T p.N167I | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV99809703; called by muse, mutect2
- ETFDH | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100310082; called by muse, mutect2, varscan2
- FAM168A | c.338C>T p.P113L (on ENST00000064778 / NM_001286050.2; = p.P104L on NM_015159.3) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.572); catalogued as rs200934649, COSV50356649; called by muse, mutect2, varscan2
- FEZF1 | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.145); catalogued as COSV58658112; called by muse, mutect2, varscan2
- FREM2 | c.6895T>G p.S2299A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV54827252; called by muse, mutect2, varscan2
- GALNT6 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62541560; called by muse, mutect2, varscan2
- GLIPR2 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs201812895; called by muse, mutect2, varscan2
- GTF3C5 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV59598708; called by muse, mutect2, varscan2
- H3C2 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV52517767, COSV52518107; called by muse, mutect2
- HECW1 | c.2377G>A p.G793S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); catalogued as rs1488073644, COSV67820918; called by muse, mutect2, varscan2
- HFE | c.91C>G p.H31D | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as COSV58512351; called by muse, mutect2, varscan2
- HGF | c.1617-2A>T p.X539_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV55944945, COSV55948530; called by muse, mutect2, varscan2
- INSRR | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs1399145308, COSV63870763; called by muse, mutect2, varscan2
- KHDC4 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV100850999; called by muse, mutect2, varscan2
- KHSRP | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV67919262; called by muse, mutect2, varscan2
- LAMA5 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs571258684, COSV53352344; called by muse, varscan2
- LRRC57 | c.635T>A p.L212H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52998974; called by muse, mutect2, varscan2
- MAP2 | c.3929G>A p.R1310H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs1170987041, COSV52280031, COSV99562288; called by muse, mutect2, varscan2
- MAP3K5 | c.4107T>G p.F1369L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV62886711; called by muse, mutect2, varscan2
- MATK | c.1325G>A p.R442H (on ENST00000310132 / NM_139355.3; = p.R443H on NM_002378.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200912092, COSV59552934, COSV59557245; called by mutect2, varscan2
- MCM4 | c.1331A>C p.K444T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV50621115; called by muse, mutect2, varscan2
- MEGF11 | c.1572G>A p.P524= | Splice Region (SNP) | VAF 39/88 reads (44%) | catalogued as rs972101500, COSV99986630; called by muse, mutect2, varscan2
- MEIS2 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.542); catalogued as rs760342372, COSV54930923; called by muse, mutect2, varscan2
- MYOM2 | c.4100C>T p.T1367M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs368659851; called by muse, mutect2, varscan2
- NALCN | c.3899A>C p.Y1300S | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV51915450; called by muse, mutect2, varscan2
- NDFIP2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1239788363, COSV99519445; called by muse, mutect2, varscan2
- NLGN3 | c.1409G>A p.R470H (on ENST00000358741 / NM_181303.2; = p.R450H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62441506; called by muse, mutect2, varscan2
- NUP43 | c.378T>A p.S126R | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV61188683; called by muse, mutect2, varscan2
- NYAP2 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV55997576; called by muse, mutect2, varscan2
- OBSCN | c.3445G>A p.G1149R | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV99483204; called by muse, mutect2, varscan2
- OPCML | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59401683; called by muse, mutect2, varscan2
- OR2D3 | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58572375; called by muse, mutect2, varscan2
- OR2H1 | c.387C>G p.H129Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV65810091; called by muse, mutect2, varscan2
- OR2J2 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65847675; called by muse, mutect2, varscan2
- OR4S2 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56745494; called by muse, mutect2, varscan2
- OR51B4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs142325891; called by muse, mutect2, varscan2
- PCBP1 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV57849647; called by muse, mutect2, varscan2
- PCDH11Y | c.3766C>A p.Q1256K | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV99292481; called by muse, mutect2, varscan2
- PCDH15 | c.1600G>T p.V534F | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV57258685; called by muse, mutect2, varscan2
- PKDREJ | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757965249, COSV53546237; called by muse, mutect2, varscan2
- PLA2R1 | c.159A>T p.Q53H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV51774479; called by muse, mutect2, varscan2
- PMPCB | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99971403; called by muse, mutect2
- POTEM | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as rs1243388183, COSV69152263; called by muse, varscan2
- PPP6R3 | c.557T>G p.L186* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99677316; called by muse, mutect2, varscan2
- PRPSAP1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.233); catalogued as rs375906385; called by muse, mutect2, varscan2
- PXDNL | c.2438A>T p.D813V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322775204, COSV62476864; called by muse, mutect2
- QRICH2 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV53150477; called by muse, mutect2, varscan2
- QTRT2 | c.1163T>G p.F388C | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV55558651; called by muse, mutect2, varscan2
- RAX | c.543+1G>T p.X181_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99900330; called by muse, mutect2
- RGS7BP | c.394T>A p.L132I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61833270; called by muse, mutect2, varscan2
- RPH3AL | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV100047773; called by muse, varscan2
- RYR2 | c.6662T>C p.L2221S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772391; called by muse, mutect2, varscan2
- SH2D3C | c.1664C>T p.P555L (on ENST00000314830 / NM_170600.3; = p.P398L on NM_005489.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs370528837; called by muse, mutect2, varscan2
- SLC14A2 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV99676044; called by muse, mutect2, varscan2
- SLC39A7 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63002229; called by muse, mutect2, varscan2
- SNRNP40 | c.643A>G p.N215D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99745639; called by muse, varscan2
- SNX29 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745385678, COSV60050101, COSV60058459; called by muse, mutect2, varscan2
- SSTR2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs752640995, COSV59534791; called by muse, mutect2, varscan2
- SYCP2 | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV100698414; called by muse, mutect2, varscan2
- TACR3 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs553885967, COSV59197525; called by muse, mutect2, varscan2
- TAS2R38 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.225); catalogued as rs144212167, COSV101516370, COSV71885866; called by muse, mutect2, varscan2
- TCF7L2 | c.1001+1G>A p.X334_splice (on ENST00000355995 / NM_001367943.1; = p.X311_splice on NM_030756.5) | Splice Site (SNP) | VAF 20/72 reads (28%) | catalogued as rs1477809102, COSV53335999; called by muse, mutect2, varscan2
- TGFB1 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55725045; called by muse, mutect2
- TIGD3 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV52887700; called by muse, mutect2, varscan2
- TNFSF4 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1232689355, COSV56055807; called by muse, mutect2, varscan2
- TUBD1 | c.1043T>A p.L348H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57871747; called by muse, mutect2, varscan2
- TXK | c.687G>T p.W229C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as COSV99972769; called by muse, mutect2, varscan2
- TYMS | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV51890265; called by muse, mutect2, varscan2
- UNC5A | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV56165064; called by muse, mutect2, varscan2
- USP29 | c.870G>T p.L290F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776599454, COSV54139599; called by muse, mutect2, varscan2
- VWC2L | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs753295197, COSV56964997, COSV56981058; called by muse, mutect2, varscan2
- WDFY3 | c.5204G>A p.R1735K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.087); catalogued as rs942714951, COSV55692516; called by muse, mutect2, varscan2
- XPO1 | c.2327T>G p.F776C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68944455; called by muse, mutect2, varscan2
- XPOT | c.1891C>G p.L631V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60343710; called by muse, mutect2, varscan2
- ZBBX | c.1676T>A p.L559Q | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs1307086248, COSV56781815; called by mutect2, varscan2
- ZFHX4 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as rs1218726795, COSV50479906; called by muse, mutect2, varscan2
- ZFPM2 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV65872410; called by muse, mutect2, varscan2
- ZNF101 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV100543621; called by muse, mutect2, varscan2
- ZNF407 | c.5046C>T p.G1682= | Splice Region (SNP) | VAF 6/13 reads (46%) | catalogued as rs761133500, COSV55241645; called by muse, mutect2
- C12orf43 | c.476_477insAGTGGC p.R159_R160insVA | In Frame Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, varscan2*
- FN1 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- IGKV1-9 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- USP31 | c.1017del p.V340Yfs*27 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- ADAM8 | c.498C>A p.T166= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV69864251; called by muse, mutect2, varscan2
- AKT1S1 | c.654C>T p.I218= (on ENST00000344175 / NM_001098633.4; = p.I238= on NM_032375.5) | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs766848323, COSV59273976; called by muse, mutect2
- AMER3 | c.210G>A p.A70= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs376219909, COSV58468297; called by muse, mutect2, varscan2
- BNIP5 | c.1134A>G p.G378= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV71325268; called by muse, mutect2, varscan2
- CFHR5 | c.588T>G p.P196= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as COSV56817642; called by muse, mutect2, varscan2
- COL3A1 | c.750C>T p.I250= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV100483631; called by muse, mutect2, varscan2
- DLC1 | c.2637C>T p.Y879= (on ENST00000276297 / NM_001348081.2; = p.Y442= on NM_006094.5) | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV52288698; called by muse, mutect2, varscan2
- DUSP29 | c.246G>A p.T82= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100633317; called by muse, mutect2
- FAM171B | c.927C>T p.V309= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100488925; called by muse, mutect2, varscan2
- FANCD2 | c.813G>T p.S271= | Silent (SNP) | VAF 61/125 reads (49%) | catalogued as rs773072936, CD072417, COSV55031830, COSV55032057; called by muse, mutect2, varscan2
- FCGRT | c.591G>A p.L197= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV55528652; called by muse, mutect2, varscan2
- FLNC | c.3294C>T p.T1098= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs753772262, COSV57949649; ClinVar: likely benign; called by muse, mutect2, varscan2
- FUBP1 | c.312A>G p.E104= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99629475; called by muse, mutect2, varscan2
- GPC3 | c.471G>A p.L157= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- GPR37 | c.1377C>A p.I459= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV58255160, COSV58257355; called by muse, mutect2, varscan2
- HMCES | c.1018C>A p.R340= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV67300088; called by muse, mutect2, varscan2
- LCE1E | c.21G>A p.Q7= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as rs1207039589, COSV64219463; called by muse, mutect2, varscan2
- LPA | c.4152G>T p.G1384= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs764191464, COSV60295985; called by muse, mutect2, varscan2
- LRRC4B | c.579G>A p.K193= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV65349151; called by muse, mutect2, varscan2
- LZTS1 | c.963G>A p.S321= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs368337680, COSV56115643; called by muse, mutect2, varscan2
- MAVS | c.240G>A p.E80= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs1407245874, COSV63926449; called by muse, mutect2, varscan2
- NLRP13 | c.162T>C p.R54= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV61619706; called by muse, mutect2, varscan2
- OR1J4 | c.678C>A p.L226= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV61589449; called by muse, mutect2, varscan2
- OSBPL6 | c.1752T>C p.S584= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs752503267, COSV51910298; called by muse, mutect2, varscan2
- OTUD4 | c.1002A>C p.P334= (on ENST00000447906 / NM_001366057.1; = p.P269= on NM_001102653.1) | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV71381378; called by muse, mutect2, varscan2
- PCDHA2 | c.1086C>T p.N362= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs139541416; called by muse, mutect2, varscan2
- POU3F4 | c.1047G>A p.S349= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs1373675392, COSV64537606; called by muse, mutect2, varscan2
- RNF150 | c.333G>A p.P111= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as COSV60786310; called by muse, mutect2, varscan2
- RSPH10B2 | c.567C>T p.H189= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs779458002; called by mutect2, varscan2
- SOX5 | c.2184C>T p.A728= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as rs138618584; called by muse, mutect2, varscan2
- THSD1 | c.1323G>C p.R441= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV51626221; called by muse, mutect2, varscan2
- UBQLN2 | c.1584C>T p.T528= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as rs763645668, COSV57738961; called by muse, mutect2, varscan2
- UBR4 | c.3312C>T p.I1104= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV64382389; called by muse, mutect2, varscan2
- XPO6 | c.3168C>T p.V1056= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1306504448, COSV58963094; called by muse, mutect2, varscan2
- YBX3 | c.732G>A p.Q244= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV54384386; called by muse, mutect2, varscan2
- ZNF782 | c.468G>A p.Q156= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as rs1001400367, COSV56650975; called by muse, mutect2, varscan2
- LEKR1 | c.*1194T>C | 3'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as COSV62960264; called by muse, mutect2, varscan2
- SLC8A3 | c.-1T>C | 5'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100776340; called by muse, mutect2, varscan2
